Somatic mutation profile of tumor specimen 0DGX3X from CCDI case PBBTYM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.8 years (4,322 days).
Specimen 0DGX3X: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d9b9b86-376f-44a7-a181-4b9c71d28769.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGX3V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca3dea4e-8555-4384-ab3e-5bb4fc803096

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 3, Silent 3, 5'UTR 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, varscan2
- GPR17 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 80/262 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs776982362, COSV55754012; called by muse, varscan2
- SERPINA5 | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1301471644; called by muse, varscan2
- TTC6 | c.2438G>A p.R813Q | Missense Mutation (SNP) | VAF 102/528 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.108); catalogued as rs753395497; called by muse, varscan2
- C12orf66 | c.601del p.Q201Rfs*58 | Frame Shift Del (DEL) | VAF 87/353 reads (25%) | called by pindel, varscan2
- CABIN1 | c.1849G>C p.V617L | Missense Mutation (SNP) | VAF 83/312 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.217); called by muse, varscan2
- CPQ | c.850G>C p.V284L | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.461); called by muse, varscan2
- GBP6 | c.1259G>C p.S420T | Missense Mutation (SNP) | VAF 160/492 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); called by muse, varscan2
- REC114 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, varscan2
- SKOR1 | c.392dup p.P132Afs*25 | Frame Shift Ins (INS) | VAF 26/179 reads (15%) | called by pindel, varscan2
- USP17L2 | c.581A>T p.H194L | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.857); called by muse, varscan2
- PRR12 | c.192G>A p.G64= (on ENST00000615927; = p.G885= on NM_020719.3) | Silent (SNP) | VAF 98/275 reads (36%) | called by muse, varscan2
- SPTBN4 | c.2031C>T p.G677= | Silent (SNP) | VAF 108/442 reads (24%) | catalogued as rs1479986490; called by muse, varscan2
- TRMT11 | c.196C>A p.R66= | Silent (SNP) | VAF 108/474 reads (23%) | called by muse, varscan2
- CCDC88B | c.676-94C>T | Intron (SNP) | VAF 7/51 reads (14%) | catalogued as rs778974800; called by muse, varscan2
- MYCL | c.496+135T>C | Intron (SNP) | VAF 70/243 reads (29%) | called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 19/172 reads (11%) | called by muse, varscan2
- USP40 | c.2381-58G>T | Intron (SNP) | VAF 14/132 reads (11%) | called by muse, varscan2
